CCDI case PBCDIC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/16e4f10c-b5f7-4978-8013-ce3689db9f0b

Demographics
Sex at birth: female; Race: american indian or alaska native.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.7 years (3,916 days).

Biospecimens (2 samples)
- Sample 0DPDHL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPDI6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
